CCDI case PBBXMJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bb0585a3-5f10-40a6-8dcd-c174c4c75708

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 14.9 years (5,427 days).

Biospecimens (3 samples)
- Sample 0DJQZK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJR16: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJR26: Tissue type: Tumor; Specimen type: Solid Tissue.
